Gene-level copy-number profile of tumor specimen ALCH-AEZK-TTP1-A from ALCHEMIST case ALCH-AEZK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 62.4 years (22,795 days).
Specimen ALCH-AEZK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e80a9787-7c0c-4ceb-9398-d19141e7617f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEZK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/7b96cd64-5a55-4267-b2f5-3a8230a9ba64

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 15,801; copy number 2: 40,386; copy number 3: 1,697; copy number 4: 682; copy number 5: 46; copy number 6: 156; copy number 7: 12; copy number 9: 32; copy number 11: 11.

Homozygous deletions (total copy number 0; autosomes only): 88 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,811,359–143,825,837, 1 gene: AC239798.1.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–1): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–1): MIR601.
- chr11:66,975,277–67,072,017, 4 genes: C11orf86, SYT12, MIR6860, RHOD.
- chr14:18,395,626–18,412,264, 1 gene: CR383658.2.
- chr15:25,215,541–25,225,284, 6 genes (within-gene range 0–2): SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr18:80,140–88,570, 1 gene: IL9RP4.
- chr19:39,328,353–39,342,372, 2 genes: GMFG, AC011445.1.
- chr20:316,860–397,559, 4 genes: NRSN2-AS1, SOX12, NRSN2, TRIB3.
- chr21:7,744,962–10,613,379, 67 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 247 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:36,784,324–38,409,527, 51 genes, copy number 5–7: KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2.
- chr8:38,408,048–38,408,742, 1 gene, copy number 5: AC087623.3.
- chr9:12,134–7,961,224, 138 genes, copy number 6–11 (broad region; genes not listed).
- chr13:112,313,467–112,321,758, 1 gene, copy number 6: LINC01043.
- chr14:18,333,726–18,341,859, 1 gene, copy number 5: CR383658.1.
- chr19:34,923,299–35,658,782, 55 genes, copy number 6: ZNF30-AS1, ZNF30, AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5, FAM187B, FAM187B2P, LSR, AC002128.2, AC002128.1, USF2, HAMP, MAG, CD22, U62631.1, MIR5196, FFAR1, FFAR3, GPR42, EEF1A1P7, LINC01531, AC002511.3, RN7SL491P, AC002511.2, AC002511.1, FFAR2, KRTDAP, DMKN, SBSN, GAPDHS, TMEM147-AS1, TMEM147, ATP4A, AD000090.1, LINC01766, AC002115.1, HAUS5, RBM42, ETV2, COX6B1.

Autosomal genes at a single copy (total copy number 1): 14,143. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
